Somatic mutation profile of tumor specimen TCGA-13-A5FU-01A (aliquot TCGA-13-A5FU-01A-11D-A403-09) from TCGA case TCGA-13-A5FU, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Retroperitoneum; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 60.9 years (22,256 days).
Specimen TCGA-13-A5FU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fce5c71e-78b2-4a9d-a645-a3e43c56f3f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-A5FU-10A (Blood Derived Normal), aliquot TCGA-13-A5FU-10A-01D-A403-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f80f87d-b72c-4e3a-b1ef-c867c527649f

The open-access MAF lists 74 somatic variants for this specimen: 55 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 18, Splice Site 4, Nonsense Mutation 1, RNA 1, Frame Shift Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.15536G>A p.R5179H | Missense Mutation (SNP) | VAF 7/16 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.116); catalogued as rs267607237, CM105472, COSV56428259, COSV56447076, COSV56496109; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 8/10 reads (80%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABLIM3 | c.1858-1G>T p.X620_splice | Splice Site (SNP) | VAF 6/81 reads (7%) | catalogued as COSV100448249; called by muse, mutect2
- AFF2 | c.1735G>T p.V579F | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV53976425, COSV99663199; called by muse, mutect2
- ANKRD12 | c.3815G>A p.R1272Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs750865713, COSV50843208; called by muse, mutect2, varscan2
- ARHGAP22 | c.1181C>G p.S394C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.401); catalogued as COSV50985181, COSV99984982; called by muse, mutect2, varscan2
- ASIC1 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99948005; called by muse, mutect2
- ATP6V0D1 | c.659C>A p.A220D | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99341098; called by muse, mutect2
- CACNA1B | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769225657, COSV99494980; called by muse, mutect2, varscan2
- CDK15 | c.273+1G>A p.X91_splice (on ENST00000652192 / NM_001366386.2; = p.X40_splice on NM_139158.2) | Splice Site (SNP) | VAF 8/47 reads (17%) | catalogued as rs754599551, COSV53634058; called by muse, mutect2, varscan2
- CEACAM20 | c.1322C>A p.S441Y | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100386840; called by muse, mutect2
- CPLX1 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100408266; called by muse, mutect2, varscan2
- CRNN | c.216G>T p.K72N | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as COSV55121045, COSV99664074; called by muse, mutect2, varscan2
- CYP51A1 | c.1141C>A p.P381T | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760669078, COSV99133731; called by muse, mutect2, varscan2
- FRS3 | c.87G>C p.E29D | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (1); PolyPhen possibly damaging (0.497); catalogued as COSV99442759; called by muse, mutect2, varscan2
- GBF1 | c.2458A>C p.N820H (on ENST00000369983 / NM_001377137.1; = p.N819H on NM_004193.3) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as COSV100890428; called by muse, mutect2, varscan2
- GUK1 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs762677870, COSV100451656; called by muse, mutect2, varscan2
- H2AC15 | c.151T>A p.Y51N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100356952; called by muse, mutect2, varscan2
- IGSF10 | c.2872G>C p.V958L | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV99178372; called by muse, mutect2, varscan2
- MAGEA11 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/44 reads (23%) | PolyPhen benign (0.043); catalogued as COSV100290450; called by muse, varscan2
- MAN1A1 | c.1210+1G>A p.X404_splice | Splice Site (SNP) | VAF 32/63 reads (51%) | catalogued as COSV63787695; called by muse, mutect2, varscan2
- MAP7D3 | c.1114G>A p.V372M | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.956); catalogued as COSV100286277; called by muse, mutect2, varscan2
- MIA2 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as COSV54483626; called by muse, mutect2, varscan2
- NCOA1 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as rs767757703, COSV56045216, COSV99945740; called by muse, mutect2, varscan2
- NTRK1 | c.899G>T p.C300F | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100693304; called by muse, mutect2, varscan2
- OPN1LW | c.601A>G p.T201A | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as COSV100885032; called by mutect2, varscan2
- OSTN | c.157A>G p.K53E | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100174212; called by muse, mutect2, varscan2
- OTOP3 | c.430G>T p.V144L | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (1); PolyPhen possibly damaging (0.72); catalogued as COSV100172759; called by muse, mutect2, varscan2
- PACS2 | c.784T>G p.F262V | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100330685; called by muse, mutect2, varscan2
- PCDH11X | c.2793C>G p.D931E | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.9); catalogued as COSV100010829; called by muse, mutect2, varscan2
- PCDHA2 | c.2141C>T p.T714M | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.246); catalogued as COSV65365402, COSV65371774; called by muse, mutect2, varscan2
- PCDHB11 | c.520C>A p.P174T | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.534); catalogued as rs781943126, COSV99504079; called by muse, mutect2
- PLXNA4 | c.5476G>A p.D1826N | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100323690; called by muse, mutect2, varscan2
- PODXL2 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.043); catalogued as COSV100686305; called by muse, mutect2, varscan2
- PRKCA | c.1047T>A p.S349R | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99434341; called by muse, mutect2, varscan2
- PTPRR | c.88T>A p.L30M | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.548); catalogued as COSV99317022; called by muse, mutect2
- RBPJL | c.854C>A p.T285K | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.721); catalogued as COSV100643475; called by muse, mutect2, varscan2
- RESF1 | c.868C>G p.P290A | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.689); catalogued as COSV100440271; called by muse, mutect2, varscan2
- RNF26 | c.680A>G p.N227S | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.322); catalogued as rs367939896; called by muse, mutect2, varscan2
- RP1 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as rs760561079, CD098189, COSV99607023; called by muse, mutect2, varscan2
- SDC3 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV100232225; called by muse, mutect2, varscan2
- SPTBN5 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as rs745375900, COSV100311138; called by muse, mutect2, varscan2
- SRRT | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs763989148, COSV100730056, COSV61453585; called by muse, mutect2, varscan2
- SSX7 | c.419G>T p.C140F | Missense Mutation (SNP) | VAF 34/342 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.211); catalogued as COSV99993810; called by muse, mutect2, varscan2
- SULF2 | c.862A>T p.M288L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as rs775285594, COSV100737127; called by muse, mutect2, varscan2
- TRPM6 | c.4237T>A p.L1413I | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV100666151; called by muse, mutect2, varscan2
- TTC14 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV99931971; called by muse, mutect2, varscan2
- UBR3 | c.3502A>G p.K1168E | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.98); catalogued as COSV99773803; called by muse, mutect2, varscan2
- WDR11 | c.572C>G p.S191C | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV99676439; called by muse, mutect2, varscan2
- XPO5 | c.2174T>C p.V725A | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV99540737; called by muse, mutect2, varscan2
- YIPF7 | c.75G>A p.M25I | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV100274442; called by muse, mutect2, varscan2
- ZDHHC19 | c.460T>A p.F154I | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV99579499; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1351G>T p.A451S | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1392497299, COSV100047995; called by muse, mutect2, varscan2
- ZNF367 | c.572-1G>A p.X191_splice | Splice Site (SNP) | VAF 10/73 reads (14%) | catalogued as COSV100930851; called by muse, mutect2, varscan2
- TAAR8 | c.536_543del p.L179Cfs*37 | Frame Shift Del (DEL) | VAF 5/38 reads (13%) | called by mutect2, pindel, varscan2
- ADGRB2 | c.2274C>A p.R758= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV99926025; called by muse, mutect2, varscan2
- BCL11A | c.1887C>T p.Y629= (on ENST00000335712 / NM_001365609.1; = p.Y663= on NM_018014.4) | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs1196538777, COSV59623973; called by muse, mutect2
- BTRC | c.999G>A p.L333= (on ENST00000370187 / NM_033637.4; = p.L297= on NM_003939.5) | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs777674405, COSV100927782; called by muse, mutect2, varscan2
- CCDC181 | c.900T>A p.T300= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV100890293; called by muse, mutect2
- CEP126 | c.1383G>A p.T461= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs764822997, COSV99680908; called by muse, mutect2, varscan2
- DESI2 | c.198A>G p.T66= | Silent (SNP) | VAF 12/115 reads (10%) | catalogued as COSV99798080; called by muse, mutect2, varscan2
- KDM6A | c.3024A>C p.A1008= | Silent (SNP) | VAF 30/487 reads (6%) | catalogued as COSV100938065; called by muse, mutect2
- LTBP3 | c.1488C>T p.S496= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV100099434; called by muse, mutect2, varscan2
- MAN2A1 | c.933C>T p.I311= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as rs367625663; called by muse, mutect2, varscan2
- MMP27 | c.975G>C p.L325= | Silent (SNP) | VAF 6/69 reads (9%) | catalogued as COSV99498367; called by muse, mutect2
- NRP1 | c.480C>T p.S160= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV55161964; called by muse, mutect2
- ODF2L | c.162T>A p.L54= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV99644016; called by muse, mutect2, varscan2
- OTUD4 | c.204T>C p.C68= (on ENST00000447906 / NM_001366057.1; = p.C3= on NM_017493.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV99669085; called by muse, mutect2, varscan2
- PDZD11 | c.324C>T p.S108= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs1295763271, COSV99333614; called by muse, mutect2, varscan2
- PIK3C2G | c.4287G>C p.T1429= (on ENST00000676171; = p.T1388= on NM_004570.5) | Silent (SNP) | VAF 7/84 reads (8%) | catalogued as COSV99849772, COSV99850931; called by muse, mutect2
- SH3RF3 | c.1173C>T p.S391= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV100512631; called by muse, mutect2, varscan2
- TENM1 | c.1885C>T p.L629= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV100949707; called by muse, mutect2
- ZNF322 | c.1113A>T p.T371= | Silent (SNP) | VAF 23/116 reads (20%) | catalogued as COSV101338462; called by muse, mutect2, varscan2
- TMEM183B | n.736G>T | RNA (SNP) | VAF 20/125 reads (16%) | called by muse, mutect2, varscan2
